Surgical pathology report (de-identified scan), TCGA case TCGA-10-0934, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-10-0934-01A (Primary Tumor).

[page 1 of 2]
***** MODIFIED REPORT REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT FALLOPIAN TUBE AND LEFT OVARY:
OVARY, HIGH-GRADE MIXED CARCINOMA COMPOSED OF HIGH-GRADE SEROUS CARCINOMA AND
ENDOMETRIOID CARCINOMA, GRADE 2. THE TUMOR EXTENDS TO THE FALLOPIAN TUBE.
Endometriosis.
- (B) RIGHT FALLOPIAN TUBE AND OVARY:
OVARY, HIGH-GRADE MIXED CARCINOMA COMPOSED OF HIGH-GRADE SEROUS CARCINOMA AND
ENDOMETRIOID CARCINOMA, GRADE 2. TUMOR EXTENDS TO THE FALLOPIAN TUBE.
- (C) UTERUS AND CERVIX:
METASTATIC HIGH-GRADE MIXED CARCINOMA IN UTERINE SEROSA AND OUTER MYOMETRIUM.
Adenomyosis.
Proliferative endometrium.
Uterine cervix, parakeratosis, hyperkeratosis, squamous metaplasia and Nabothian cyst.
- (D) APPENDIX:
APPENDIX, METASTATIC HIGH-GRADE MIXED CARCINOMA.
Endometriosis.
- (E) OMENTUM:
METASTATIC HIGH-GRADE MIXED CARCINOMA IN ADIPOSE TISSUE.
Three lymph nodes, no tumor present.
- (F) CUL-DE-SAC NODULE:
METASTATIC HIGH-GRADE MIXED CARCINOMA.
- (G) PORTION OF ANTERIOR STOMACH:
Heterotopic pancreas in
gastric wall.
- (H) OMENTUM #2:
METASTATIC HIGH-GRADE MIXED CARCINOMA IN ADIPOSE TISSUE.
Two lymph nodes, no tumor present.

GROSS DESCRIPTION

- (A) LEFT TUBE AND LEFT OVARY – A distorted, enlarged, firm, partially cystic ovary (9.0 x 10.0 x 9.0 cm) with attached slightly dilated fallopian tube (6.0 cm long and 0.7 cm in diameter).
The surface of the tube is irregular and focally bosselated. The ovarian tumor is predominantly necrotic and hemorrhagic with foci of viable tan-pink, friable tumor. Four representative sections are submitted for frozen.
SECTION CODE: A1-A4, frozen section; A5-A14, representative sections of tube and ovary.
*FS/DX: HIGH GRADE CARCINOMA.
- (B) RIGHT TUBE AND OVARY – An enlarged ovary (6.0 x 4.0 x 2.5 cm) with an attached slightly dilated fallopian tube (7.2 cm long and 1.3 cm in diameter).
The ovarian cortical surface is bosselated.
SECTION CODE: B1-B5, tube and ovary.
- (C) UTERUS AND CERVIX - A 12.5 x 8.0 x 4.5 cm uterus with attached cervix.

[page 2 of 2]
[REDACTED]

The serosal surface of the uterus is diffusely coated with firm tan-pink tumor.

The ectocervix and endocervix are grossly normal. The endometrium is 2.0 mm thick and free of polyps or other masses. No myometrial masses are present, but the myometrium is grossly suspicious for adenomyosis.

SECTION CODE: C1-C4, uterine serosal tumor; C5, C6, cervix; C7-C10, endomyometrium. [REDACTED]

(D) APPENDIX - A 4.5 x 3.0 x 2.5 cm irregularly shaped appendix.

The external surface of the appendix has attached a tan-pink, firm tumor. Sectioning demonstrates a normal appendiceal lumen.

SECTION CODE: D1-D3, representative sections of appendix with mass involving wall. [REDACTED]

(E) OMENTUM - An irregular fragment of adipose tissue (15.0 x 10.0 x 1.0 cm).

Multiple tan-white nodular areas are present ranging from 0.2 x 0.2 x 0.2 to 7.0 x 2.0 x 0.4 cm.

SECTION CODE: E1-E25, representative sections of omentum. [REDACTED]

(F) CUL-DE-SAC NODULE - A single nodule (1.0 x 0.6 x 0.4 cm). The specimen is bisected and entirely submitted in F [REDACTED]

(G) PORTION OF ANTERIOR STOMACH WALL - Two segments of stomach wall (2.0 x 1.5 x 1.0 cm) with unremarkable pink-tan mucosa. The wall is thickened (1.0 cm).

SECTION CODE: G1, frozen section; G2, G3, remainder of the specimen. [REDACTED]

*FS/DX: HETEROTOPIC PANCREAS. [REDACTED]

(H) OMENTUM #2 - An irregular fragment of adipose tissue (15.0 x 4.0 x 1.0 cm). No lymph nodes or lesions are grossly identified.

SECTION CODE: H1-H8, omentum [REDACTED]

CLINICAL HISTORY

[REDACTED] pelvic mass.

[REDACTED]

Start of ADDENDUM

Source: NCI Genomic Data Commons file 376e2ecc-df36-4249-85f8-2e026bdf1aaa (TCGA-10-0934.A5C94C47-086B-4D69-A03F-74DF709FDC56.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).